Somatic mutation profile of tumor specimen TCGA-29-1696-01A (aliquot TCGA-29-1696-01A-01W-0633-09) from TCGA case TCGA-29-1696, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 43.3 years (15,818 days).
Specimen TCGA-29-1696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491bc555-3f5a-4fe2-83d2-8d11ee83b870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1696-10A (Blood Derived Normal), aliquot TCGA-29-1696-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a9e5c2-760f-4b73-8451-01211ce85143

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 38, Silent 15, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARR3 | c.1065T>A p.H355Q | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52104898; called by muse, mutect2, varscan2
- ATXN7L2 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63992660; called by muse, mutect2, varscan2
- CAMKK1 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV50122382, COSV50123265; called by muse, mutect2, varscan2
- CAMSAP3 | c.3500G>T p.C1167F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50346381; called by muse, mutect2, varscan2
- CD226 | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54614748; called by muse, mutect2, varscan2
- CDK12 | c.3521C>G p.A1174G | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV71001170; called by muse, mutect2, varscan2
- CDKL2 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56734725; called by muse, mutect2, varscan2
- CLEC5A | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV69397570; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DEF6 | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57354891; called by muse, mutect2, varscan2
- DIO3 | c.490A>C p.N164H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63774307; called by muse, mutect2, varscan2
- DMXL2 | c.1618-1G>T p.X540_splice | Splice Site (SNP) | VAF 119/232 reads (51%) | catalogued as COSV51852121, COSV51857870; called by muse, mutect2, varscan2
- DOP1B | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV67694982; called by muse, mutect2, varscan2
- FASTKD5 | c.2285C>A p.S762Y | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV53908222; called by muse, mutect2, varscan2
- FLG2 | c.6944C>A p.S2315Y | Missense Mutation (SNP) | VAF 568/820 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66171306; called by muse, mutect2, varscan2
- FLG2 | c.4538G>A p.G1513D | Missense Mutation (SNP) | VAF 257/1003 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101165951, COSV66171314; called by muse, mutect2, varscan2
- GATC | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1302400469, COSV56664097; called by muse, mutect2, varscan2
- HLTF | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.049); catalogued as COSV59501397; called by muse, mutect2, varscan2
- HSPA1B | c.1907C>A p.T636N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.348); catalogued as COSV65128360; called by muse, mutect2, varscan2
- HTATSF1 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 435/734 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV54480131, COSV54480338, COSV54481279; called by muse, mutect2, varscan2
- INO80 | c.2280G>C p.E760D | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62740781, COSV62741023; called by muse, mutect2, varscan2
- KIF20B | c.4150C>G p.Q1384E (on ENST00000371728 / NM_001284259.2; = p.Q1344E on NM_016195.4) | Missense Mutation (SNP) | VAF 164/200 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53312546, COSV53318071; called by muse, mutect2, varscan2
- KRTAP26-1 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 168/334 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV62129162; called by muse, mutect2, varscan2
- LAMC3 | c.1698dup p.G567Rfs*24 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | catalogued as rs775904966; called by mutect2, pindel
- MYOM1 | c.3422C>T p.T1141I | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55297843; called by muse, mutect2, varscan2
- OR5M1 | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 151/305 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV73202321; called by muse, mutect2, varscan2
- P4HTM | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100637593; called by muse, mutect2, varscan2
- P4HTM | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100637594; called by muse, mutect2, varscan2
- PTPRD | c.2292G>A p.M764I | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61971039; called by muse, mutect2, varscan2
- RASA2 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99656577; called by muse, mutect2, varscan2
- RASA2 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99656581; called by muse, mutect2, varscan2
- SCN7A | c.872A>T p.E291V | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV69273621; called by muse, mutect2, varscan2
- SIN3B | c.2305G>C p.D769H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56135456; called by muse, mutect2, varscan2
- SLC10A1 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV53683450; called by muse, mutect2, varscan2
- SLC7A14 | c.1795C>A p.L599I | Missense Mutation (SNP) | VAF 100/187 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.108); catalogued as COSV51586960; called by muse, mutect2, varscan2
- SMC4 | c.458A>T p.K153M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV58450697; called by muse, mutect2, varscan2
- TNC | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375940361; called by muse, mutect2, varscan2
- TP53 | c.652del p.V218Cfs*29 | Frame Shift Del (DEL) | VAF 36/64 reads (56%) | catalogued as COSV52795822, COSV53209108; called by mutect2, pindel, varscan2
- TRANK1 | c.6853C>A p.L2285M | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100084032; called by muse, mutect2
- UNC79 | c.2399G>T p.C800F (on ENST00000393151 / NM_001346218.2; = p.C623F on NM_020818.5) | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1566690601, COSV56391413, COSV99059721; called by muse, mutect2, varscan2
- USP53 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV56796613; called by muse, mutect2, varscan2
- VCAM1 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 50/116 reads (43%) | catalogued as COSV54120992; called by muse, mutect2, varscan2
- AMIGO1 | c.667dup p.L223Pfs*6 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.4238dup p.E1414Rfs*19 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by pindel, varscan2
- MYRIP | c.1552dup p.H518Pfs*42 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- SLC12A4 | c.3124_3142del p.N1042Gfs*16 | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- TCAF1 | c.2556C>A p.Y852* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- ACIN1 | c.3744G>A p.R1248= | Silent (SNP) | VAF 4/102 reads (4%) | catalogued as rs1297329748, COSV99400088; called by muse, mutect2
- CSMD1 | c.3489A>C p.G1163= (on ENST00000520002; = p.G1162= on NM_033225.6) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100151767; called by muse, mutect2
- CSMD1 | c.1635C>G p.L545= (on ENST00000520002; = p.L544= on NM_033225.6) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV59359544; called by muse, mutect2, varscan2
- FGF14 | c.210T>A p.G70= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV65946029; called by muse, mutect2, varscan2
- FLNB | c.4329C>T p.F1443= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV55882729; called by muse, mutect2, varscan2
- GSDMC | c.351C>A p.L117= | Silent (SNP) | VAF 154/316 reads (49%) | catalogued as COSV52697762; called by muse, mutect2, varscan2
- IL25 | c.321C>T p.H107= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as rs766959581, COSV59307246; called by muse, mutect2, varscan2
- ITGA2B | c.1695C>T p.N565= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- KHDC3L | c.180A>G p.G60= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV64869584; called by muse, mutect2, varscan2
- MAVS | c.159C>T p.D53= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as rs779275322, COSV63927321; called by muse, mutect2, varscan2
- PCDHGA10 | c.1923G>T p.A641= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs578221269, COSV54001333; called by muse, mutect2, varscan2
- SPAG6 | c.693A>T p.S231= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as COSV57622665; called by muse, mutect2, varscan2
- SV2B | c.1803G>C p.G601= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV57701134; called by muse, mutect2, varscan2
- SYTL2 | c.136C>T p.L46= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as COSV60361781; called by muse, mutect2, varscan2
- TMEM130 | c.1161G>A p.P387= (on ENST00000416379 / NM_001134450.2; = p.P375= on NM_152913.3) | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs782198839, COSV59560044; called by muse, mutect2, varscan2
